Somatic mutation profile of tumor specimen C3L-00445-01 (aliquot CPT0130410009) from CPTAC case C3L-00445, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 74.8 years (27,320 days).
Specimen C3L-00445-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7461bafa-c1ae-4c38-800a-0ea66e7c66be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00445-31 (Blood Derived Normal), aliquot CPT0130530002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3af37f67-7ebb-47b5-ae00-a7a2e8c6243f

The open-access MAF lists 253 somatic variants for this specimen: 172 protein-altering or splice-affecting, 57 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 153, Silent 57, Intron 12, Frame Shift Del 5, Nonsense Mutation 4, 5'UTR 4, Frame Shift Ins 4, 3'UTR 4, Splice Region 3, 5'Flank 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRYBB3 | c.493G>C p.G165R | Missense Mutation (SNP) | VAF 218/593 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74315490, CM053823, COSV53194120; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.845G>C p.R282P | Missense Mutation (SNP) | VAF 255/646 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs730882008, CM004344, COSV52689673, COSV52773873, COSV52969460, COSV53068318; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1751C>T p.S584F (on ENST00000404938 / NM_001163941.2; = p.S139F on NM_178559.6) | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV51724163; called by muse, mutect2, varscan2
- ABCD1 | c.1747G>A p.V583M | Missense Mutation (SNP) | VAF 282/462 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1569541120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO8 | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 158/488 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs778843591; called by muse, varscan2
- APBB1 | c.1400A>G p.Y467C | Missense Mutation (SNP) | VAF 127/581 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1434609942; called by muse, mutect2, varscan2
- APOBEC1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 122/248 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762259232; called by muse, mutect2, varscan2
- ATP8A2 | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1336615167; called by muse, mutect2, varscan2
- BCL9L | c.3721C>T p.P1241S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs759315320; called by muse, mutect2, varscan2
- BUD23 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs141991727; called by muse, mutect2, varscan2
- CD55 | c.963_965del p.T322del | In Frame Del (DEL) | VAF 76/181 reads (42%) | catalogued as rs1424932158; called by pindel, varscan2
- CDKN2A | c.58G>C p.A20P | Missense Mutation (SNP) | VAF 113/305 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs760065045, COSV58693206, COSV58699768, COSV58729858; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP1 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 146/629 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.793); catalogued as rs763919892, COSV52848858, COSV52849023; called by muse, mutect2, varscan2
- COL4A3 | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 76/202 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV67421142; called by muse, mutect2, varscan2
- CPSF7 | c.233G>A p.R78H (on ENST00000394888 / NM_001136040.4; = p.R121H on NM_024811.4) | Missense Mutation (SNP) | VAF 59/342 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); catalogued as rs376706196; called by muse, mutect2, varscan2
- CTNNA2 | c.2663C>G p.T888S (on ENST00000402739 / NM_001282597.3; = p.T840S on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100561791; called by muse, mutect2, varscan2
- DLGAP3 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 127/279 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as rs762482299, COSV52391347, COSV99333045; called by muse, mutect2, varscan2
- E2F7 | c.177dup p.F60Ifs*12 | Frame Shift Ins (INS) | VAF 60/168 reads (36%) | catalogued as rs771114476; called by mutect2, varscan2
- FLG | c.1594C>A p.H532N | Missense Mutation (SNP) | VAF 234/646 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs758635510, COSV64236350; called by muse, mutect2, varscan2
- FSHR | c.1621G>T p.A541S | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99065635; called by muse, mutect2, varscan2
- GAB1 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV53756271; called by muse, mutect2, varscan2
- H3C4 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs754191024; called by muse, mutect2, varscan2
- HSPG2 | c.11428G>T p.A3810S | Missense Mutation (SNP) | VAF 86/165 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV65933226; called by muse, mutect2, varscan2
- IGBP1P2 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs761955741; called by muse, mutect2, varscan2
- ITIH2 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.025); catalogued as COSV100623493; called by muse, mutect2, varscan2
- KMT2D | c.14126C>A p.S4709* | Nonsense Mutation (SNP) | VAF 61/109 reads (56%) | catalogued as COSV56413333; called by muse, mutect2, varscan2
- KRT6C | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 365/730 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771618302, COSV52876377, COSV99359765; called by muse, mutect2, varscan2
- LRFN3 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768565870; called by muse, mutect2, varscan2
- LSM14A | c.1229G>C p.R410T | Missense Mutation (SNP) | VAF 93/405 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV101471762; called by muse, mutect2, varscan2
- MAGEL2 | c.3532G>A p.A1178T | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.048); catalogued as rs749213689, COSV100046083; called by muse, mutect2, varscan2
- MICALL1 | c.2480G>A p.R827K | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99316978; called by muse, mutect2
- MINAR1 | c.625T>C p.C209R | Missense Mutation (SNP) | VAF 102/382 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs201828671; called by muse, mutect2, varscan2
- MR1 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 188/463 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs202146104; called by muse, mutect2, varscan2
- MUC6 | c.2911C>T p.P971S | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV70149880; called by muse, mutect2, varscan2
- MYRF | c.1891G>A p.A631T (on ENST00000278836 / NM_001127392.3; = p.A622T on NM_013279.4) | Missense Mutation (SNP) | VAF 167/566 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.227); catalogued as COSV99608036; called by muse, mutect2, varscan2
- NPHP3 | c.2770G>A p.D924N | Missense Mutation (SNP) | VAF 164/437 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs141073933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPR3 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 123/702 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs753335569; called by muse, mutect2, varscan2
- OR2M5 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63547200; called by muse, varscan2
- OR4C16 | c.860T>C p.L287P | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761916811; called by muse, mutect2, varscan2
- OR4D10 | c.597G>C p.M199I | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV73260131; called by muse, mutect2, varscan2
- OR51B5 | c.537C>G p.H179Q | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs150082635; called by muse, mutect2, varscan2
- PCDHA11 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 207/886 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs376574285; called by muse, mutect2, varscan2
- PIDD1 | c.2023G>A p.G675S | Missense Mutation (SNP) | VAF 89/355 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200628750; called by muse, mutect2, varscan2
- PIEZO1 | c.5290G>A p.E1764K | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.2); catalogued as rs749976222; called by muse, mutect2, varscan2
- PLEKHA1 | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.467); catalogued as rs748416070; called by muse, mutect2, varscan2
- PRPF4B | c.1960A>G p.I654V | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs763897085; called by muse, mutect2, varscan2
- SCNN1B | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 118/629 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.342); catalogued as COSV56304638; called by muse, mutect2, varscan2
- SERPINB11 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as rs1454333018, COSV101236233; called by muse, mutect2, varscan2
- SGCE | c.109G>A p.A37T (on ENST00000647096; = p.V37M on NM_003919.3) | Missense Mutation (SNP) | VAF 46/444 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.996); catalogued as rs1562916805; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHANK2 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 181/387 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53597899; called by muse, mutect2, varscan2
- SLC38A10 | c.2936A>G p.H979R | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as rs754530635; called by muse, mutect2, varscan2
- SLCO1A2 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757093777, COSV100261231; called by muse, mutect2, varscan2
- SMC6 | c.3187A>G p.R1063G | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs767770240; called by muse, mutect2, varscan2
- SRGAP2 | c.2755C>T p.R919W (on ENST00000624873 / NM_001170637.4; = p.R920W on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/370 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs570977025; called by muse, mutect2
- SYN1 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs764201581; called by muse, mutect2, varscan2
- THOC3 | c.45G>C p.Q15H | Missense Mutation (SNP) | VAF 149/624 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV54198474; called by muse, mutect2, varscan2
- TOPAZ1 | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1285671436; called by muse, mutect2, varscan2
- TRAPPC12 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV100160563; called by muse, mutect2, varscan2
- TRAT1 | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV99041493; called by muse, mutect2, varscan2
- TUT4 | c.1951A>G p.I651V | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.369); catalogued as rs920297425; called by muse, mutect2, varscan2
- TYR | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 123/321 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as rs200471520; called by muse, mutect2, varscan2
- UNKL | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1205099534; called by muse, mutect2, varscan2
- WDFY4 | c.3194C>T p.P1065L | Missense Mutation (SNP) | VAF 129/280 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1404781165; called by muse, mutect2, varscan2
- XKR4 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 80/268 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs376937606, COSV59335308; called by muse, varscan2
- YOD1 | c.58G>C p.G20R | Missense Mutation (SNP) | VAF 70/125 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.329); catalogued as rs1371529379; called by muse, mutect2, varscan2
- ZCCHC2 | c.3169G>A p.G1057S | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.532); catalogued as rs765522998; called by mutect2, varscan2
- ZKSCAN5 | c.1642C>A p.P548T | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58743495; called by muse, mutect2
- ZNF169 | c.1346A>G p.Q449R | Missense Mutation (SNP) | VAF 64/375 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.538); catalogued as rs148933432; called by muse, mutect2, varscan2
- ZNF208 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 105/336 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV68108801; called by muse, mutect2, varscan2
- ABCC11 | c.3382G>T p.G1128C | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); called by muse, mutect2
- AC068580.4 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- ADAMTS12 | c.4290G>T p.E1430D | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.358); called by muse, mutect2
- ADCYAP1 | c.418A>T p.S140C | Missense Mutation (SNP) | VAF 100/306 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ADGRF3 | c.1320dup p.N441Efs*15 (on ENST00000311519 / NM_001145168.1; = p.N242Efs*15 on NM_153835.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 50/237 reads (21%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.17869G>T p.A5957S | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- AFG3L2 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 81/1026 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AK9 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ARHGAP30 | c.941-6T>G | Splice Region (SNP) | VAF 122/383 reads (32%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.914G>T p.R305L | Missense Mutation (SNP) | VAF 156/674 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF11 | c.302C>G p.S101* | Nonsense Mutation (SNP) | VAF 51/135 reads (38%) | called by muse, mutect2, varscan2
- ARHGEF40 | c.2207G>A p.G736E | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASXL3 | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- BDKRB2 | c.812T>A p.L271Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BIRC6 | c.4676G>T p.G1559V | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPTF | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 108/316 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- C1QTNF4 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 61/327 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- C1QTNF9B | c.261C>G p.I87M | Missense Mutation (SNP) | VAF 38/355 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CA4 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 68/399 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- CARD11 | c.1432dup p.S478Ffs*8 | Frame Shift Ins (INS) | VAF 27/283 reads (10%) | called by muse*, pindel
- CEMIP | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 159/540 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFHR5 | c.1223A>T p.Q408L | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- CHODL | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHRM2 | c.1264T>A p.W422R | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTN3 | c.181A>T p.R61* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- COL24A1 | c.4279C>A p.H1427N | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSAG3 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 250/888 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CTNNAL1 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.756); called by muse, varscan2
- DAP3 | c.361G>C p.A121P | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- DAP3 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- DNM1L | c.470A>G p.D157G | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYSF | c.2971G>C p.G991R | Missense Mutation (SNP) | VAF 182/592 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPM2AIP1 | c.384G>T p.L128F | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT1 | c.11827del p.T3943Pfs*2 | Frame Shift Del (DEL) | VAF 51/187 reads (27%) | called by mutect2, pindel, varscan2
- FGD3 | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 80/343 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FPR1 | c.419G>C p.S140T | Missense Mutation (SNP) | VAF 97/323 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- FSCN1 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 94/328 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FTSJ3 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 83/223 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FZD6 | c.1041A>T p.K347N | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GATA5 | c.1136A>T p.Q379L | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GLYR1 | c.682-6C>G | Splice Region (SNP) | VAF 56/196 reads (29%) | called by muse, mutect2, varscan2
- HIBCH | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.07); called by muse, mutect2
- HNF4G | c.849dup p.R284Efs*21 (on ENST00000354370 / NM_001330561.2; = p.R331Efs*21 on NM_004133.5) | Frame Shift Ins (INS) | VAF 107/509 reads (21%) | called by mutect2, pindel, varscan2
- KAT7 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- KCNT1 | c.2962C>G p.L988V (on ENST00000488444; = p.L1007V on NM_020822.3) | Missense Mutation (SNP) | VAF 62/320 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- KIFC2 | c.1999G>A p.G667R | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- LAMA5 | c.9227+1G>A p.X3076_splice | Splice Site (SNP) | VAF 89/270 reads (33%) | called by muse, mutect2
- LMBRD2 | c.1228A>T p.T410S | Missense Mutation (SNP) | VAF 58/301 reads (19%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- MCF2 | c.1686C>A p.S562R | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MMRN2 | c.1187A>C p.Y396S | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMUT | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- MTX1 | c.291T>A p.S97R | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUCL3 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- MYH8 | c.3458T>A p.L1153Q | Missense Mutation (SNP) | VAF 115/313 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MYO16 | c.1695A>T p.K565N | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- MYO9A | c.4880del p.G1627Afs*4 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | called by mutect2, pindel, varscan2
- MYSM1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NGLY1 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 122/302 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.445); called by muse, varscan2
- OR10G2 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 95/176 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- OR13C8 | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2M5 | c.537T>G p.C179W | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OR51F1 | c.134C>A p.A45D | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- OR6B1 | c.922A>T p.S308C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8K3 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- OTOF | c.3655G>T p.G1219C (on ENST00000272371 / NM_194248.3; = p.G472C on NM_004802.4) | Missense Mutation (SNP) | VAF 74/413 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P4HA3 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PAN3 | c.2145A>T p.E715D | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- PCDH8 | c.400C>A p.R134S | Missense Mutation (SNP) | VAF 45/286 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PDZRN3 | c.2273A>G p.Y758C | Missense Mutation (SNP) | VAF 98/212 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PEG3 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PLK1 | c.1341T>G p.D447E | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- PLXNB1 | c.4612del p.D1538Tfs*11 | Frame Shift Del (DEL) | VAF 24/217 reads (11%) | called by mutect2, pindel, varscan2
- PNPLA6 | c.2804G>T p.R935L (on ENST00000414982 / NM_001166111.2; = p.R887L on NM_006702.5) | Missense Mutation (SNP) | VAF 114/287 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- POM121L12 | c.676G>T p.V226F | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.98); called by muse, varscan2
- POP1 | c.2239C>G p.P747A | Missense Mutation (SNP) | VAF 112/447 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPP1R9A | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- PRICKLE3 | c.1559A>G p.H520R | Missense Mutation (SNP) | VAF 103/207 reads (50%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RGS9 | c.344C>A p.P115Q | Missense Mutation (SNP) | VAF 188/553 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- RIPK4 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 140/367 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- RYK | c.1505G>A p.G502E (on ENST00000620660 / NM_001005861.2; = p.G499E on NM_002958.4) | Missense Mutation (SNP) | VAF 232/615 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAXO2 | c.430C>A p.P144T | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SH3BP4 | c.2083G>T p.G695C | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SHANK1 | c.6280C>T p.P2094S | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- SLC17A4 | c.174C>G p.S58R | Missense Mutation (SNP) | VAF 79/274 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLITRK6 | c.389_392del p.D130Vfs*20 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- SNRNP200 | c.1840C>T p.L614= | Splice Region (SNP) | VAF 123/310 reads (40%) | called by muse, mutect2, varscan2
- STARD9 | c.5984A>T p.K1995M | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- STK31 | c.2515G>T p.A839S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM3 | c.2255G>A p.R752K | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- TET2 | c.5836G>A p.G1946S | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TFAP2D | c.401T>C p.L134P | Missense Mutation (SNP) | VAF 126/343 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- THSD7B | c.3364T>A p.C1122S (on ENST00000272643; = p.C1120S on NM_001316349.2) | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); called by muse, mutect2
- TIAM2 | c.2474G>A p.G825E | Missense Mutation (SNP) | VAF 98/214 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR5 | c.1522T>C p.Y508H | Missense Mutation (SNP) | VAF 152/309 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TMEM132D | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- TNMD | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- TRIM48 | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 102/644 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, varscan2
- TUT4 | c.1219G>C p.A407P | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VGF | c.1784del p.R595Pfs*79 | Frame Shift Del (DEL) | VAF 93/327 reads (28%) | called by mutect2, pindel, varscan2
- ZNF235 | c.18G>T p.E6D | Missense Mutation (SNP) | VAF 112/411 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF268 | c.2096G>T p.S699I | Missense Mutation (SNP) | VAF 206/284 reads (73%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF274 | c.281C>G p.P94R (on ENST00000610905; = p.P62R on NM_016325.3) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- ZNF568 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA6 | c.3624G>A p.L1208= | Silent (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- ABCF2 | c.630G>T p.R210= | Silent (SNP) | VAF 32/260 reads (12%) | called by muse, mutect2, varscan2
- ABHD16B | c.519C>T p.L173= | Silent (SNP) | VAF 40/774 reads (5%) | catalogued as rs766084482; called by muse, mutect2
- ANGPTL3 | c.504A>T p.V168= | Silent (SNP) | VAF 82/212 reads (39%) | called by muse, mutect2, varscan2
- BRINP3 | c.1885C>T p.L629= | Silent (SNP) | VAF 111/351 reads (32%) | catalogued as COSV66517530; called by muse, mutect2, varscan2
- BTN3A1 | c.1482A>G p.L494= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- CARMIL2 | c.2625G>A p.E875= | Silent (SNP) | VAF 74/416 reads (18%) | catalogued as rs755823264, COSV58029007; called by muse, mutect2, varscan2
- CDH18 | c.2184C>T p.S728= | Silent (SNP) | VAF 84/418 reads (20%) | catalogued as rs1279662292, COSV56924162, COSV99935390; called by muse, mutect2, varscan2
- CEACAM16 | c.1086C>T p.L362= | Silent (SNP) | VAF 30/435 reads (7%) | catalogued as COSV69186605; called by muse, mutect2
- CEP152 | c.666A>G p.Q222= | Silent (SNP) | VAF 34/233 reads (15%) | called by muse, mutect2, varscan2
- CLASRP | c.585G>T p.S195= | Silent (SNP) | VAF 137/348 reads (39%) | called by muse, mutect2, varscan2
- CRYBG2 | c.1215G>T p.L405= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- CYP11B1 | c.288C>T p.D96= | Silent (SNP) | VAF 28/572 reads (5%) | catalogued as rs5284; ClinVar: likely benign; called by muse, mutect2
- DUSP22 | c.405C>G p.L135= | Silent (SNP) | VAF 38/310 reads (12%) | catalogued as COSV60527126; called by muse, mutect2, varscan2
- EBLN1 | c.105G>A p.K35= | Silent (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- ERCC2 | c.912C>T p.H304= | Silent (SNP) | VAF 86/290 reads (30%) | catalogued as rs369477332; called by muse, mutect2, varscan2
- ESX1 | c.1173C>T p.I391= | Silent (SNP) | VAF 126/208 reads (61%) | called by muse, varscan2
- ETV1 | c.115C>T p.L39= | Silent (SNP) | VAF 39/163 reads (24%) | catalogued as COSV54139601; called by muse, mutect2, varscan2
- FAM110A | c.486G>A p.S162= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV55726752; called by muse, mutect2
- FAM184B | c.423C>T p.A141= | Silent (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- FNBP4 | c.2439C>G p.L813= | Silent (SNP) | VAF 17/124 reads (14%) | catalogued as COSV55448560; called by muse, mutect2, varscan2
- GAL3ST1 | c.1221C>T p.N407= | Silent (SNP) | VAF 47/117 reads (40%) | called by muse, mutect2, varscan2
- GPR26 | c.966C>T p.G322= | Silent (SNP) | VAF 121/266 reads (45%) | called by muse, mutect2, varscan2
- H2AP | c.105T>A p.V35= | Silent (SNP) | VAF 80/168 reads (48%) | called by muse, mutect2, varscan2
- HHIP | c.1728T>C p.N576= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs368724167; called by muse, varscan2
- KIAA1614 | c.1995G>A p.A665= | Silent (SNP) | VAF 200/511 reads (39%) | catalogued as rs372602361; called by muse, mutect2, varscan2
- LATS2 | c.1344T>C p.R448= | Silent (SNP) | VAF 30/159 reads (19%) | called by muse, mutect2, varscan2
- MGAT3 | c.588G>A p.K196= | Silent (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- MUC5AC | c.14988C>T p.H4996= | Silent (SNP) | VAF 51/253 reads (20%) | catalogued as rs1484690379, COSV64369524; called by muse, mutect2, varscan2
- NLRP8 | c.2424T>C p.L808= | Silent (SNP) | VAF 15/154 reads (10%) | called by muse, mutect2
- NUP88 | c.765A>T p.G255= | Silent (SNP) | VAF 68/174 reads (39%) | called by muse, mutect2, varscan2
- OR11H1 | c.294T>C p.F98= | Silent (SNP) | VAF 12/68 reads (18%) | called by mutect2, varscan2
- OR2A25 | c.609G>A p.V203= | Silent (SNP) | VAF 93/318 reads (29%) | called by muse, mutect2, varscan2
- OR52I2 | c.225C>T p.I75= | Silent (SNP) | VAF 91/527 reads (17%) | catalogued as rs371482534; called by muse, varscan2
- POM121C | c.3366C>T p.P1122= (on ENST00000607367; = p.P880= on NM_001099415.3) | Silent (SNP) | VAF 231/821 reads (28%) | catalogued as COSV57548940; called by muse, mutect2, varscan2
- PPP1R13L | c.2046G>T p.A682= | Silent (SNP) | VAF 99/325 reads (30%) | catalogued as COSV62908365; called by muse, mutect2, varscan2
- PPP1R26 | c.3372C>T p.A1124= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as rs1196412770; called by muse, mutect2, varscan2
- PPP5C | c.618G>A p.R206= | Silent (SNP) | VAF 56/199 reads (28%) | catalogued as rs1178676493; called by muse, mutect2, varscan2
- PRDM15 | c.240A>C p.A80= | Silent (SNP) | VAF 194/480 reads (40%) | called by muse, mutect2, varscan2
- RAD21L1 | c.1020G>A p.R340= | Silent (SNP) | VAF 50/332 reads (15%) | called by muse, mutect2, varscan2
- RHPN1 | c.1419C>T p.T473= | Silent (SNP) | VAF 71/223 reads (32%) | called by muse, mutect2, varscan2
- RUBCN | c.594G>A p.P198= | Silent (SNP) | VAF 85/606 reads (14%) | catalogued as rs374081741; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCFD2 | c.2040A>G p.P680= | Silent (SNP) | VAF 99/213 reads (46%) | called by muse, mutect2, varscan2
- SLC38A4 | c.1233T>G p.P411= | Silent (SNP) | VAF 15/167 reads (9%) | called by muse, mutect2
- TBXT | c.75G>A p.E25= | Silent (SNP) | VAF 393/776 reads (51%) | catalogued as rs1180620109, COSV99752923; called by muse, mutect2, varscan2
- TMEM114 | c.531C>T p.L177= | Silent (SNP) | VAF 72/533 reads (14%) | called by muse, mutect2, varscan2
- TRIM49B | c.1293A>C p.I431= | Silent (SNP) | VAF 23/157 reads (15%) | called by muse, mutect2, varscan2
- TRIM50 | c.429G>A p.L143= | Silent (SNP) | VAF 53/956 reads (6%) | catalogued as rs1554544845, COSV60791911; called by muse, mutect2
- TRNAU1AP | c.459C>T p.A153= | Silent (SNP) | VAF 93/230 reads (40%) | called by muse, mutect2, varscan2
- TRPC5 | c.504C>T p.I168= | Silent (SNP) | VAF 119/200 reads (60%) | catalogued as COSV53296070; called by muse, mutect2, varscan2
- TTN | c.96474C>A p.T32158= (on ENST00000591111; = p.T24734= on NM_003319.4) | Silent (SNP) | VAF 166/418 reads (40%) | called by muse, mutect2, varscan2
- TTYH3 | c.1488C>T p.S496= | Silent (SNP) | VAF 111/212 reads (52%) | called by muse, mutect2, varscan2
- VGLL3 | c.771A>G p.P257= | Silent (SNP) | VAF 121/360 reads (34%) | called by muse, mutect2, varscan2
- VPS13B | c.87A>T p.S29= | Silent (SNP) | VAF 63/309 reads (20%) | called by muse, mutect2, varscan2
- ZNF219 | c.1224C>T p.R408= | Silent (SNP) | VAF 62/326 reads (19%) | catalogued as rs1232843161; called by muse, mutect2, varscan2
- ZNF729 | c.3666A>G p.P1222= | Silent (SNP) | VAF 75/226 reads (33%) | called by muse, mutect2, varscan2
- ZNF862 | c.3061C>T p.L1021= | Silent (SNP) | VAF 126/500 reads (25%) | catalogued as COSV56223703; called by muse, mutect2, varscan2
- AC142381.4 | n.499+32264C>A | Intron (SNP) | VAF 87/390 reads (22%) | called by muse, mutect2, varscan2
- ACR | c.565+15G>A | Intron (SNP) | VAF 159/504 reads (32%) | catalogued as rs774080258; called by muse, mutect2, varscan2
- ACTR3BP2 | n.840A>G | RNA (SNP) | VAF 48/167 reads (29%) | called by muse, mutect2, varscan2
- AHI1 | chr6:135497825 C>T | 5'Flank (SNP) | VAF 27/97 reads (28%) | called by muse, mutect2, varscan2
- CASP2 | c.475+492C>T | Intron (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- COL4A1 | c.442-18C>G | Intron (SNP) | VAF 76/273 reads (28%) | called by muse, mutect2, varscan2
- DEPDC1B | c.49-505C>A | Intron (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- DPP9 | c.2092-92G>A | Intron (SNP) | VAF 19/132 reads (14%) | catalogued as rs753549896; called by muse, mutect2, varscan2
- EFHC1 | c.*1534A>G | 3'UTR (SNP) | VAF 161/369 reads (44%) | called by muse, mutect2, varscan2
- EIF1 | c.-31C>G | 5'UTR (SNP) | VAF 14/193 reads (7%) | called by muse, mutect2
- ELP3 | c.*3del | 3'UTR (DEL) | VAF 65/185 reads (35%) | called by mutect2, pindel, varscan2
- LRRC6 | c.10+65G>T | Intron (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- NELL1 | c.56-3424C>A | Intron (SNP) | VAF 44/212 reads (21%) | called by muse, mutect2, varscan2
- P4HA3 | c.*130C>T | 3'UTR (SNP) | VAF 109/245 reads (44%) | catalogued as rs1053610500; called by muse, mutect2, varscan2
- RAB4A | c.-69C>T | 5'UTR (SNP) | VAF 34/115 reads (30%) | called by muse, mutect2, varscan2
- SLC25A36 | c.385+3746G>A | Intron (SNP) | VAF 68/489 reads (14%) | catalogued as rs193029986; called by muse, mutect2, varscan2
- SLC27A1 | c.-6C>T | 5'UTR (SNP) | VAF 157/464 reads (34%) | called by muse, mutect2, varscan2
- SLC2A14 | c.88-7022C>A | Intron (SNP) | VAF 157/289 reads (54%) | called by muse, mutect2, varscan2
- SPANXN4 | chrX:143034661 G>T | 3'Flank (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- ST6GAL1 | c.706-8246C>T | Intron (SNP) | VAF 182/511 reads (36%) | catalogued as rs771695221; called by muse, mutect2, varscan2
- TMEM230 | c.-50C>T | 5'UTR (SNP) | VAF 219/817 reads (27%) | called by muse, mutect2, varscan2
- TRPM3 | c.1816-882G>A | Intron (SNP) | VAF 38/164 reads (23%) | catalogued as COSV100676662; called by muse, mutect2, varscan2
- ZIC4 | c.*48G>A | 3'UTR (SNP) | VAF 54/262 reads (21%) | catalogued as COSV67174118; called by muse, mutect2, varscan2
- ZNF529 | chr19:36573420 C>T | 5'Flank (SNP) | VAF 64/255 reads (25%) | called by muse, mutect2, varscan2
